Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A6GZ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A6GZ-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

CASE NUMBER:

DIAGNOSIS: Right adrenal, adrenalectomy: Pheochromocytoma.

Final

Final Results

NOTE: Immunohistochemistry studies were performed on section 1D. The tumor is positive for chromogranin, synaptophysin and CD56. It is negative for inhibin. S100 highlights the sustentacular cells. This immunochemical profile confirms the diagnosis.

The immunoperoxidase tests performed here were developed and their performance characteristics determined by the

They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Allocate Order to Protocol:

Brief

Clinical History: right

adrenal mass Specimen Taken For Protocol

Yes

PROCEDURE: Pre-Operative Diagnosis: right adrenal mass Post-Operative Diagnosis:

right adrenal mass Operative Findings: right adrenal mass

SPECIMENS SUBMITTED: 1. ADRENAL MASS, RIGHT

GROSS DESCRIPTION: One specimen is received fresh, labeled with the patient's name and medical record number, and further specified as "right adrenal mass". It consists of a round red-tan soft tissue weighing 9.8 grams and measuring 2.7 x 2.7 x 1.5 cm. The specimen is inked in black and opened to reveal a red-tan homogeneous cut surface with no visible adrenal tissue. Approximately 1.1 x 0.5 x 0.5 cm of tissue is procured for the , and 1.5 x 1.5 x 1.5 cm of tissue is procured for Dr.

The procurement was performed by Dr.

In the Gross Room, the specimen matches the above description. Representative sections are submitted in white cassettes labeled 1A-1D.

Gross description dictated by

No consultants

#

Requested By:

Do not file in Medical Record

[page 2 of 2]
#

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file 4d54fffd-f3f1-476b-96a0-ab53aa8c4642 (TCGA-QR-A6GZ.BC451841-9284-4745-94DE-A7A2DD17A342.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).